Somatic mutation profile of tumor specimen TCGA-BP-4982-01A (aliquot TCGA-BP-4982-01A-01D-1462-08) from TCGA case TCGA-BP-4982, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 42.3 years (15,451 days).
Specimen TCGA-BP-4982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aed9e244-d956-4423-9266-9c0b8fd2bf35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4982-11A (Solid Tissue Normal), aliquot TCGA-BP-4982-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/498f0e33-8dc2-4a94-911c-10d7a752214c

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 24, Silent 9, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.576A>G p.I192M | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57714564; called by muse, mutect2, varscan2
- ACIN1 | c.1535A>T p.Y512F | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as COSV52980805; called by muse, mutect2, varscan2
- AGRN | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV65071867; called by muse, mutect2, varscan2
- AP4B1 | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV56726570; called by muse, varscan2
- AZU1 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145363133; called by muse, mutect2, varscan2
- BPI | c.663C>A p.F221L (on ENST00000262865; = p.F217L on NM_001725.3) | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53407778; called by muse, mutect2, varscan2
- CLCC1 | c.905T>A p.V302D (on ENST00000356970 / NM_001377464.1; = p.V252D on NM_015127.5) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56765004; called by muse, mutect2, varscan2
- CRYGA | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV58018654; called by muse, mutect2
- CUX1 | c.769C>A p.L257I (on ENST00000292535 / NM_181552.4; = p.L268I on NM_001913.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52911539; called by muse, mutect2
- GLDN | c.1460C>A p.T487N | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV59091917; called by muse, mutect2, varscan2
- KRTAP10-3 | c.22G>T p.V8F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV59975624; called by muse, mutect2, varscan2
- LUC7L3 | c.278T>G p.L93R | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV53588981; called by muse, mutect2, varscan2
- NDE1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as COSV61275625; called by muse, mutect2, varscan2
- NDE1 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV61275645; called by muse, mutect2, varscan2
- NDUFAF3 | c.184A>G p.S62G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as COSV58247003; called by muse, mutect2, varscan2
- NIT2 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67630671; called by mutect2, varscan2
- NIT2 | c.249C>T p.G83= | Splice Region (SNP) | VAF 19/99 reads (19%) | catalogued as COSV67630678; called by muse, mutect2
- NSD3 | c.1891A>G p.K631E | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57621426; called by muse, mutect2, varscan2
- OR2H2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.626); catalogued as COSV63544135; called by muse, mutect2, varscan2
- PBRM1 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV56284913, COSV56297688; called by muse, mutect2, varscan2
- SETBP1 | c.2557C>A p.L853M | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV56333763; called by muse, mutect2, varscan2
- SPAG8 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs199668156, COSV52415476; called by muse, mutect2, varscan2
- TCP11 | c.1423C>A p.Q475K (on ENST00000512012; = p.Q413K on NM_018679.5) | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.151); catalogued as COSV55135542; called by muse, mutect2, varscan2
- UBE2H | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV62921558; called by muse, mutect2, varscan2
- UBL4B | c.37T>A p.C13S | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61944670; called by muse, mutect2, varscan2
- XPC | c.2546A>C p.K849T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.298); catalogued as COSV53207307; called by muse, mutect2, varscan2
- ZNF283 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as COSV61032397; called by muse, mutect2, varscan2
- CCDC59 | c.13_14del p.R5Afs*11 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel
- ERAP1 | c.2496del p.P833Hfs*12 | Frame Shift Del (DEL) | VAF 31/240 reads (13%) | called by mutect2, pindel, varscan2
- CCDC185 | c.1560C>T p.H520= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs749893943, COSV64821666; called by muse, mutect2, varscan2
- FTL | c.78G>A p.Q26= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs749884917, COSV53171516; called by muse, mutect2, varscan2
- HPSE2 | c.942C>T p.I314= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs142810016, COSV65187751; called by muse, mutect2, varscan2
- MTREX | c.186T>C p.N62= | Silent (SNP) | VAF 88/308 reads (29%) | catalogued as COSV57929345; called by muse, mutect2, varscan2
- PARP1 | c.1905C>G p.P635= | Silent (SNP) | VAF 98/455 reads (22%) | catalogued as COSV64691812; called by muse, mutect2, varscan2
- PLB1 | c.342C>A p.I114= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV59833665; called by muse, varscan2
- PSMF1 | c.636C>T p.P212= | Silent (SNP) | VAF 94/468 reads (20%) | catalogued as rs376298956, COSV55675607; called by muse, mutect2, varscan2
- SCAP | c.3630A>T p.S1210= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV55547491; called by muse, mutect2, varscan2
- SUPV3L1 | c.1875C>A p.L625= | Silent (SNP) | VAF 72/294 reads (24%) | catalogued as COSV62846114; called by muse, mutect2, varscan2
